TCGA case TCGA-23-1028 — Ovarian Serous Cystadenocarcinoma (TCGA-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary; Tissue source site: Cedars Sinai. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/df53c3c0-3605-4d2b-bdc7-96d9beab27ea

Demographics
Sex at birth: female; Race: white; Ethnicity: hispanic or latino; Age at index: 43 years; Vital status: Alive.

Diagnoses (2)
1. Serous cystadenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8441/3; ICD-10 code: C56.9; Tissue or organ of origin: Ovary; Site of resection or biopsy: Ovary; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 43.9 years (16,018 days); Year of diagnosis: 2004; Method of diagnosis: Surgical Resection; FIGO stage: Stage IIIC; Tumor grade: G3; Prior treatment: No; Days to last follow up: 1,503 days (4.1 years).
   Pathology details: Lymphatic invasion present: Yes; Residual tumor measurement: 1-10 mm; Vascular invasion present: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Treatment intent type: Adjuvant; Days to treatment start: 26 days; Days to treatment end: 110 days; Number of cycles: 4; Treatment dose: 2,900 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Days to treatment start: 26 days; Days to treatment end: 110 days; Number of cycles: 4; Treatment dose: 1,600 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Doxorubicin; Initial disease status: Recurrent Disease; Days to treatment start: 173 days; Days to treatment end: 229 days; Number of cycles: 3; Treatment dose: 201 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Initial disease status: Recurrent Disease; Days to treatment start: 749 days (2.1 years); Days to treatment end: 859 days (2.4 years); Number of cycles: 6; Treatment dose: 2,802 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Docetaxel; Initial disease status: Recurrent Disease; Days to treatment start: 749 days (2.1 years); Days to treatment end: 859 days (2.4 years); Number of cycles: 6; Treatment dose: 846 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Topotecan; Initial disease status: Progressive Disease; Days to treatment start: 908 days (2.5 years); Days to treatment end: 1,006 days (2.8 years); Number of cycles: 11; Treatment dose: 41 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Doxorubicin; Initial disease status: Progressive Disease; Days to treatment start: 1,112 days (3.0 years); Days to treatment end: 1,335 days (3.7 years); Number of cycles: 8; Treatment dose: 418 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Topotecan; Initial disease status: Progressive Disease; Days to treatment start: 1,140 days (3.1 years); Days to treatment end: 1,153 days (3.2 years); Number of cycles: 3; Treatment dose: 10 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Initial disease status: Progressive Disease; Days to treatment start: 1,363 days (3.7 years); Days to treatment end: 1,461 days (4.0 years); Number of cycles: 5; Treatment dose: 2,667 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Initial disease status: Progressive Disease; Days to treatment start: 1,461 days (4.0 years); Days to treatment end: 1,461 days (4.0 years); Number of cycles: 1; Treatment dose: 525 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine; Initial disease status: Progressive Disease; Days to treatment start: 1,461 days (4.0 years); Days to treatment end: 1,461 days (4.0 years); Number of cycles: 1; Treatment dose: 1,552 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Initial disease status: Progressive Disease; Days to treatment start: 1,468 days (4.0 years); Days to treatment end: 1,489 days (4.1 years); Number of cycles: 2; Treatment dose: 100 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine; Initial disease status: Progressive Disease; Days to treatment start: 1,468 days (4.0 years); Days to treatment end: 1,489 days (4.1 years); Number of cycles: 2; Treatment dose: 3,100 mg; Route of administration: Intravenous.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Metastasis of diagnosis 1 (Serous cystadenocarcinoma, NOS). Age at diagnosis: 44.2 years (16,151 days); Days to diagnosis: 133 days; Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Progressive Disease; Days to treatment start: 133 days.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for recurrent disease.

Follow-up (3 entries)
- Day 133 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 133 days; Evidence of recurrence type: Convincing Image Source.
- Days to follow up: 1,503 days (4.1 years); Disease response: With Tumor.
- Progression or recurrence: Yes; Progression or recurrence type: Distant; Evidence of progression type: Convincing Image Source; Timepoint: Post Initial Treatment.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-23-1028-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 0.8; Intermediate dimension: 0.6; Shortest dimension: 0.4.
  Slide TCGA-23-1028-01A-01-TS1: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 80; Percent normal cells: 10; Percent necrosis: 5; Percent stromal cells: 10.
  Slide TCGA-23-1028-01A-01-BS1: Section location: Bottom; Percent tumor cells: 70; Percent tumor nuclei: 75; Percent normal cells: 15; Percent necrosis: 5; Percent stromal cells: 10.
- Sample TCGA-23-1028-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-23-1028-10B: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Serous Cystadenocarcinoma; Tumor status: With tumor; History neoadjuvant treatment: No; Anatomic organ subdivision: Left; Method initial path diagnosis: Tumor resection; Lymphovascular invasion indicator: Yes.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 4: Therapy regimen: Progression.
- Follow-up form: Treatment outcome first course: Complete Remission/Response; Tumor status: With tumor.

The TCGA Pan-Cancer Clinical Data Resource (Liu et al., Cell 2018) lists this case as redacted by TCGA at the time of its curation; its follow-up endpoints are therefore not restated here.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; sample TCGA-23-1028-01): tumor purity 0.82, ploidy 1.74, whole-genome doublings 0 (call status: legacy_call).
